FM case AD1669 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/99451dad-cf5c-45d5-9b20-846d147b4d96

Male, 58.0 years: diagnosis not reported by GDC; metastasis biopsied or resected from the vertebral column. Tumor nuclei on the sequenced sample's slide: 90% (pathologist estimate recorded by GDC). Sample type: Metastatic.
